Somatic mutation profile of tumor specimen TCGA-XU-A931-01A (aliquot TCGA-XU-A931-01A-11D-A423-09) from TCGA case TCGA-XU-A931, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 61.4 years (22,432 days).
Specimen TCGA-XU-A931-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20affa8d-6496-433e-a101-a337cc6171cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A931-10A (Blood Derived Normal), aliquot TCGA-XU-A931-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf1817ca-be74-497a-9681-99cb02c08f04

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TENM2 | c.751C>G p.P251A (on ENST00000518659 / NM_001122679.2; = p.P60A on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.989); catalogued as rs1405085102, COSV101318525; called by muse, mutect2, varscan2
- TULP3 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs761395470; called by muse, mutect2, varscan2
- ICE1 | c.1353A>C p.E451D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- RALA | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SHPRH | c.2965G>A p.G989R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TPTE2 | c.63A>G p.E21= | Splice Region (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- APOL1 | c.885A>T p.S295= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- PBRM1 | c.411T>C p.A137= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV56307929; called by muse, mutect2
- DCHS2 | n.3741G>A | RNA (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
